Somatic mutation profile of tumor specimen TCGA-US-A77E-01A (aliquot TCGA-US-A77E-01A-11D-A32N-08) from TCGA case TCGA-US-A77E, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 73.2 years (26,745 days).
Specimen TCGA-US-A77E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ed2b3215-a2d9-419f-932b-0071b103f83d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-US-A77E-11A (Solid Tissue Normal), aliquot TCGA-US-A77E-11A-11D-A32N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4853b47f-d1cb-4dd4-80d5-d230c81e7ca0

The open-access MAF lists 77 somatic variants for this specimen: 66 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 60, Silent 11, Nonsense Mutation 4, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAS | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 124/397 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs121913495, CM158823, COSV55670349, COSV55671845; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS8 | c.1292C>T p.A431V | Missense Mutation (SNP) | VAF 44/202 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs764943940, COSV99960934; called by muse, mutect2, varscan2
- ALS2CL | c.142C>T p.R48W | Missense Mutation (SNP) | VAF 34/225 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.226); catalogued as rs143519761; called by muse, mutect2, varscan2
- APOA4 | c.991C>T p.P331S | Missense Mutation (SNP) | VAF 101/507 reads (20%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.936); catalogued as COSV100759318; called by muse, mutect2, varscan2
- ARMC7 | c.452C>T p.S151L | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1426829512, COSV55460923; called by muse, mutect2, varscan2
- ATP2C1 | c.2588C>G p.P863R | Missense Mutation (SNP) | VAF 40/257 reads (16%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.999); catalogued as COSV60756913, COSV60760753; called by muse, mutect2
- ATP7A | c.791A>T p.E264V | Missense Mutation (SNP) | VAF 120/353 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.255); catalogued as COSV58446774; called by muse, mutect2, varscan2
- C5AR1 | c.95C>T p.T32M | Missense Mutation (SNP) | VAF 69/363 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.27); catalogued as rs200400919, COSV61892222; called by muse, mutect2, varscan2
- C7 | c.2464G>A p.A822T | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs780107037, COSV57474906; called by muse, mutect2, varscan2
- CAMSAP3 | c.3263G>A p.R1088H | Missense Mutation (SNP) | VAF 82/416 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs754308415, COSV50335834; called by muse, mutect2, varscan2
- CARD11 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 93/610 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV62717739; called by muse, mutect2, varscan2
- CNIH3 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 59/400 reads (15%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as rs751126399, COSV55276056; called by muse, mutect2, varscan2
- COL12A1 | c.350C>T p.S117L | Missense Mutation (SNP) | VAF 55/407 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs753747530, COSV59393279; called by muse, mutect2, varscan2
- COL6A2 | c.2938G>A p.V980M | Missense Mutation (SNP) | VAF 40/168 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as rs140020002, COSV99385434; ClinVar: likely benign; called by muse, mutect2, varscan2
- DNAH1 | c.4265C>T p.T1422M | Missense Mutation (SNP) | VAF 21/212 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.332); catalogued as rs745784100, COSV101325747; called by muse, mutect2, varscan2
- DOCK10 | c.5635C>T p.R1879C | Missense Mutation (SNP) | VAF 75/474 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1213034885, COSV51350825; called by muse, mutect2, varscan2
- ELAVL2 | c.942T>G p.N314K | Missense Mutation (SNP) | VAF 22/548 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.377); catalogued as COSV99806163; called by muse, mutect2
- ENGASE | c.1766C>T p.P589L | Missense Mutation (SNP) | VAF 64/332 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs771673399, COSV56135705; called by muse, mutect2, varscan2
- ESRRA | c.959G>A p.R320Q | Missense Mutation (SNP) | VAF 56/240 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.3); catalogued as rs374006359; called by muse, mutect2, varscan2
- FBLN2 | c.3008G>A p.G1003E | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55485131; called by muse, mutect2, varscan2
- FHOD1 | c.289G>A p.G97S | Missense Mutation (SNP) | VAF 45/390 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1276797977, COSV99264111; called by muse, mutect2, varscan2
- FIBIN | c.289G>A p.V97M | Missense Mutation (SNP) | VAF 33/180 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs188656817, COSV100590425; called by muse, mutect2, varscan2
- FOXN4 | c.1163C>T p.P388L | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as rs778183505, COSV54494443; called by muse, mutect2, varscan2
- GABRD | c.934G>A p.V312I | Missense Mutation (SNP) | VAF 38/237 reads (16%) | SIFT tolerated (0.9); PolyPhen probably damaging (0.993); catalogued as rs774201718, COSV66080730; called by muse, mutect2, varscan2
- GBA3 | c.1037T>G p.I346S | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as COSV72438152; called by muse, mutect2, varscan2
- IDO1 | c.302A>T p.K101M | Missense Mutation (SNP) | VAF 80/360 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV53714275; called by muse, mutect2, varscan2
- IFT46 | c.719T>C p.I240T (on ENST00000264021 / NM_001168618.2; = p.I291T on NM_020153.3) | Missense Mutation (SNP) | VAF 82/535 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as rs782820961, COSV50594371; called by muse, mutect2, varscan2
- INSM1 | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 36/238 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as COSV59605258; called by muse, mutect2, varscan2
- KCNQ2 | c.329_332del p.S110Cfs*22 | Frame Shift Del (DEL) | VAF 74/706 reads (10%) | catalogued as rs1064796151; called by pindel, varscan2
- KIAA1549 | c.4216C>G p.R1406G | Missense Mutation (SNP) | VAF 72/488 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54306746, COSV54315244; called by muse, mutect2, varscan2
- KIF27 | c.1847T>G p.I616R | Missense Mutation (SNP) | VAF 34/897 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV99926970; called by muse, mutect2
- KIFC3 | c.1090G>A p.V364I | Missense Mutation (SNP) | VAF 40/203 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as rs146824728; called by muse, mutect2, varscan2
- KLF4 | c.1232C>A p.S411Y | Missense Mutation (SNP) | VAF 139/854 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV65928934, COSV65928982; called by muse, mutect2, varscan2
- KMT2A | c.1325G>A p.R442Q | Missense Mutation (SNP) | VAF 163/808 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV63286147; called by muse, mutect2, varscan2
- MAP3K7CL | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 66/400 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs756879316, COSV99726608; called by muse, mutect2, varscan2
- MCM3AP | c.4768C>T p.H1590Y | Missense Mutation (SNP) | VAF 59/343 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV52440118; called by muse, mutect2, varscan2
- MED16 | c.2469G>A p.W823* | Nonsense Mutation (SNP) | VAF 14/180 reads (8%) | catalogued as rs1157121168, COSV54126734; called by muse, mutect2
- NECTIN3 | c.1295G>A p.R432Q | Missense Mutation (SNP) | VAF 101/499 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.097); catalogued as rs15611, COSV60551510; called by muse, mutect2, varscan2
- NES | c.4226C>A p.S1409Y | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100957864; called by muse, mutect2
- NLRP4 | c.802A>G p.K268E | Missense Mutation (SNP) | VAF 85/456 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56714688; called by muse, mutect2, varscan2
- NLRP8 | c.1754G>A p.R585K | Missense Mutation (SNP) | VAF 31/208 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV52588095; called by muse, mutect2, varscan2
- OR4A47 | c.541C>A p.P181T | Missense Mutation (SNP) | VAF 28/786 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV101487063, COSV71444879, COSV71445121; called by muse, mutect2
- OR4S2 | c.397A>C p.I133L | Missense Mutation (SNP) | VAF 48/991 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV100412652; called by muse, mutect2
- OR5H1 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 68/392 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.244); catalogued as rs267599953, COSV100641608, COSV63402483; called by muse, mutect2, varscan2
- PLCG2 | c.1615A>T p.K539* | Nonsense Mutation (SNP) | VAF 47/249 reads (19%) | catalogued as COSV63869869; called by muse, mutect2, varscan2
- POLR1B | c.1714C>T p.P572S | Missense Mutation (SNP) | VAF 96/608 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.16); catalogued as COSV54498794; called by muse, mutect2, varscan2
- PREX1 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 207/1405 reads (15%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.679); catalogued as rs920268436, COSV64252183; called by muse, mutect2, varscan2
- RCOR2 | c.1009C>T p.Q337* | Nonsense Mutation (SNP) | VAF 259/994 reads (26%) | catalogued as COSV100036191; called by muse, mutect2, varscan2
- SERINC1 | c.706A>G p.N236D | Missense Mutation (SNP) | VAF 60/278 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV60102134; called by muse, mutect2, varscan2
- SOX17 | c.838G>T p.G280C | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.184); catalogued as COSV52025923; called by muse, mutect2, varscan2
- ST6GAL2 | c.1024C>T p.R342C | Missense Mutation (SNP) | VAF 72/431 reads (17%) | PolyPhen probably damaging (1); catalogued as rs533150647, COSV62415930; called by muse, mutect2, varscan2
- STC2 | c.833G>A p.G278D | Missense Mutation (SNP) | VAF 139/693 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as rs778297660, COSV54180034; called by muse, mutect2, varscan2
- SUPT20HL1 | c.952G>A p.V318I | Missense Mutation (SNP) | VAF 103/500 reads (21%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.987); catalogued as rs753320066; called by muse, mutect2, varscan2
- TBC1D9 | c.175C>T p.R59W | Missense Mutation (SNP) | VAF 34/212 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746432332, COSV65932318; called by muse, mutect2, varscan2
- TECPR1 | c.2305C>A p.H769N | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV101130483; called by muse, mutect2
- TPM1 | c.493G>T p.V165L | Missense Mutation (SNP) | VAF 57/315 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV99146937; called by muse, mutect2, varscan2
- TRBV3-1 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 70/498 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.343); catalogued as rs959033905; called by muse, mutect2, varscan2
- TTN | c.50306C>T p.S16769L (on ENST00000591111; = p.S9345L on NM_003319.4) | Missense Mutation (SNP) | VAF 96/493 reads (19%) | PolyPhen benign (0.053); catalogued as rs1184146630, COSV60088654; called by muse, mutect2, varscan2
- UNC80 | c.127G>T p.E43* | Nonsense Mutation (SNP) | VAF 33/190 reads (17%) | catalogued as COSV55892494; called by muse, mutect2, varscan2
- VCAN | c.10112C>T p.S3371L | Missense Mutation (SNP) | VAF 63/265 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54106063; called by muse, mutect2, varscan2
- XYLT1 | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 80/441 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs764139799, COSV99761754; called by muse, mutect2, varscan2
- ZBTB4 | c.367C>T p.P123S | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.043); catalogued as COSV100263281; called by muse, mutect2
- ZEB2 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 33/191 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs769433211, COSV57957363; called by muse, mutect2, varscan2
- ZNF212 | c.1312C>T p.H438Y | Missense Mutation (SNP) | VAF 61/367 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV100242363; called by muse, mutect2, varscan2
- BRAF | c.1583_1597del p.T528_Q533delinsK (on ENST00000288602 / NM_001374244.1; = p.T488_Q493delinsK on NM_004333.6 and 3 other RefSeq transcripts) | In Frame Del (DEL) | VAF 46/324 reads (14%) | called by mutect2, pindel
- TRAV17 | c.322T>G p.F108V | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- CDH11 | c.429G>A p.S143= | Silent (SNP) | VAF 61/317 reads (19%) | catalogued as rs574599418, COSV51763164; called by muse, mutect2, varscan2
- COL5A2 | c.1662A>G p.K554= | Silent (SNP) | VAF 54/398 reads (14%) | catalogued as COSV100880308; called by muse, mutect2, varscan2
- DNAJC13 | c.1077C>A p.L359= | Silent (SNP) | VAF 53/286 reads (19%) | catalogued as COSV53451100; called by muse, mutect2, varscan2
- DPP6 | c.1962C>T p.G654= (on ENST00000377770 / NM_001364500.2; = p.G592= on NM_001936.5) | Silent (SNP) | VAF 12/154 reads (8%) | catalogued as rs924792880, COSV100125280; called by muse, mutect2
- FOXI1 | c.282G>A p.P94= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV100089327; called by muse, mutect2, varscan2
- GAA | c.1725C>T p.Y575= | Silent (SNP) | VAF 98/490 reads (20%) | catalogued as rs112517802, CM093565, COSV56408834; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- KRT36 | c.930C>T p.I310= | Silent (SNP) | VAF 20/137 reads (15%) | catalogued as rs769372926, COSV60203504; called by muse, mutect2, varscan2
- POMC | c.576C>T p.D192= | Silent (SNP) | VAF 20/94 reads (21%) | catalogued as rs767274513, COSV53034998; called by muse, mutect2, varscan2
- SHKBP1 | c.1776C>T p.G592= | Silent (SNP) | VAF 88/581 reads (15%) | catalogued as COSV52540181; called by muse, mutect2, varscan2
- TRAV38-2DV8 | c.349G>A p.*117= | Silent (SNP) | VAF 20/127 reads (16%) | catalogued as rs374940368; called by muse, mutect2, varscan2
- TRDN | c.2151T>C p.G717= | Silent (SNP) | VAF 20/130 reads (15%) | catalogued as COSV62122661; called by muse, mutect2
